Somatic mutation profile of tumor specimen TCGA-B0-4816-01A (aliquot TCGA-B0-4816-01A-01D-1501-10) from TCGA case TCGA-B0-4816, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 49.6 years (18,133 days).
Specimen TCGA-B0-4816-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5729d2d-fe9f-40e5-9c5a-2ab7c5a3ab6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-4816-11A (Solid Tissue Normal), aliquot TCGA-B0-4816-11A-02D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d90c45f-3114-4d4f-b18a-e4e074df6b14

The open-access MAF lists 61 somatic variants for this specimen: 52 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 8, Frame Shift Del 5, Splice Site 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPI | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55013979; called by muse, mutect2, varscan2
- ANKRD26 | c.2771T>G p.L924R | Missense Mutation (SNP) | VAF 87/400 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV65775307; called by muse, mutect2, varscan2
- BOD1L1 | c.1674A>T p.E558D | Missense Mutation (SNP) | VAF 113/526 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.062); catalogued as COSV50011813; called by muse, mutect2, varscan2
- BTAF1 | c.5038A>G p.S1680G | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV56433500; called by muse, mutect2, varscan2
- DNAI4 | c.800+1G>A p.X267_splice | Splice Site (SNP) | VAF 110/511 reads (22%) | catalogued as rs754566779, COSV100925251, COSV64018474; called by muse, mutect2, varscan2
- DQX1 | c.1729T>G p.L577V | Missense Mutation (SNP) | VAF 51/310 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV52045844; called by muse, mutect2, varscan2
- FAT2 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV55818974; called by muse, mutect2, varscan2
- FBN2 | c.2366G>T p.G789V | Missense Mutation (SNP) | VAF 67/311 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52510626, COSV52542559; called by muse, mutect2, varscan2
- FKBPL | c.458A>G p.E153G | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV64322449; called by muse, mutect2, varscan2
- FUBP1 | c.1517C>G p.A506G | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV53930278; called by muse, mutect2, varscan2
- HOXA2 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV56066124; called by muse, mutect2, varscan2
- IGKV1D-16 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs374098825; called by muse, mutect2, varscan2
- KANK4 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV62986619; called by muse, varscan2
- KDM5C | c.1606G>T p.G536W | Missense Mutation (SNP) | VAF 98/227 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64764689; called by muse, mutect2, varscan2
- KLB | c.1294G>T p.A432S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.241); catalogued as COSV57301574; called by muse, varscan2
- LTBP4 | c.151G>A p.A51T (on ENST00000308370 / NM_001042544.1; = p.L7= on NM_003573.2) | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.025); catalogued as COSV52580887; called by muse, mutect2, varscan2
- MACF1 | c.20476G>A p.A6826T (on ENST00000372915; = p.A4871T on NM_012090.5) | Missense Mutation (SNP) | VAF 20/126 reads (16%) | catalogued as COSV57119585; called by muse, varscan2
- MACF1 | c.20477C>T p.A6826V (on ENST00000372915; = p.A4871V on NM_012090.5) | Missense Mutation (SNP) | VAF 20/129 reads (16%) | catalogued as COSV57119601; called by muse, varscan2
- MTO1 | c.1568A>T p.Q523L (on ENST00000370300 / NM_133645.3; = p.Q498L on NM_012123.4) | Missense Mutation (SNP) | VAF 102/563 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV64773737; called by muse, mutect2, varscan2
- NDUFB6 | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV63083312; called by muse, mutect2, varscan2
- NSA2 | c.592G>A p.G198S | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.143); catalogued as COSV57187953; called by muse, mutect2, varscan2
- NXF1 | c.664G>C p.G222R | Missense Mutation (SNP) | VAF 92/406 reads (23%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.717); catalogued as COSV53673879; called by mutect2, varscan2
- P2RY4 | c.1034G>T p.S345I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV100997061; called by muse, mutect2, varscan2
- PANK1 | c.1786G>T p.D596Y (on ENST00000307534 / NM_148977.2; = p.D312Y on NM_138316.4) | Missense Mutation (SNP) | VAF 78/419 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV56807960; called by muse, mutect2, varscan2
- PBRM1 | c.2627G>T p.R876L | Missense Mutation (SNP) | VAF 88/360 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56269665, COSV56274390; called by muse, mutect2, varscan2
- PKHD1 | c.6255A>T p.K2085N | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV61873788; called by muse, mutect2, varscan2
- PPIB | c.605G>A p.C202Y | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV55520110; called by muse, mutect2, varscan2
- PTPN13 | c.1399A>C p.T467P | Missense Mutation (SNP) | VAF 69/288 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.424); catalogued as COSV57406803; called by muse, mutect2, varscan2
- RBM28 | c.2256G>C p.K752N | Missense Mutation (SNP) | VAF 109/436 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56162909; called by muse, mutect2, varscan2
- RBPJ | c.1234C>G p.R412G | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.717); catalogued as COSV60750894; called by muse, mutect2, varscan2
- RIMBP2 | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1275261141, COSV55470967; called by muse, mutect2, varscan2
- RYR2 | c.12430C>T p.R4144C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1298823746, CM087241, CM1515199, COSV63683395; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC63 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 132/602 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV64599453; called by muse, mutect2, varscan2
- SEL1L3 | c.1523C>A p.P508H | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV53540344; called by muse, mutect2, varscan2
- SEMA4G | c.830A>T p.K277M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.705); catalogued as COSV52967924; called by muse, mutect2, varscan2
- SF3B1 | c.3523G>T p.D1175Y | Missense Mutation (SNP) | VAF 63/230 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59213172; called by muse, mutect2, varscan2
- SPEF2 | c.3617T>C p.L1206P | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.201); catalogued as COSV61547888; called by muse, mutect2, varscan2
- TECPR2 | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.313); catalogued as rs758992021, COSV63970327; called by muse, mutect2, varscan2
- TGFBR3 | c.1460G>T p.C487F | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53025105; called by muse, mutect2, varscan2
- THADA | c.814T>A p.L272M | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV57682830; called by muse, mutect2, varscan2
- TMC3 | c.3202G>A p.G1068S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.01); catalogued as COSV63925252; called by muse, varscan2
- TMEM100 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV70118004; called by muse, mutect2, varscan2
- ZNF169 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762656741, COSV61764168; called by muse, mutect2, varscan2
- ZNF57 | c.1321A>T p.I441F | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV60983338; called by muse, mutect2, varscan2
- ZZEF1 | c.6184G>A p.V2062M | Missense Mutation (SNP) | VAF 91/415 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs761113925, COSV67557276; called by muse, mutect2, varscan2
- HPDL | c.959_963del p.K320Tfs*12 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | called by mutect2, pindel, varscan2
- MAP3K14 | c.63del p.E21Dfs*38 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- NEURL4 | c.3633del p.K1211Nfs*57 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | called by mutect2, pindel, varscan2
- OR51D1 | c.25_26dup p.I10Lfs*3 | Frame Shift Ins (INS) | VAF 37/204 reads (18%) | called by mutect2, pindel, varscan2
- PPARD | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- SND1 | c.805del p.H269Tfs*21 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- ZNF33A | c.869del p.S290Lfs*8 (on ENST00000458705 / NM_006974.3; = p.S291Lfs*8 on NM_006954.2) | Frame Shift Del (DEL) | VAF 34/157 reads (22%) | called by mutect2, pindel, varscan2
- CD163L1 | c.3288G>A p.G1096= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV58015484; called by muse, mutect2, varscan2
- CYLC1 | c.648A>G p.T216= | Silent (SNP) | VAF 42/90 reads (47%) | catalogued as COSV61411843; called by muse, mutect2, varscan2
- DNHD1 | c.14007C>T p.A4669= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV54434838; called by muse, mutect2, varscan2
- LRIG2 | c.259T>C p.L87= | Silent (SNP) | VAF 87/455 reads (19%) | catalogued as COSV63161942; called by muse, mutect2, varscan2
- PPIB | c.606C>T p.C202= | Silent (SNP) | VAF 25/151 reads (17%) | catalogued as rs143287832; ClinVar: likely benign; called by muse, mutect2, varscan2
- RAB3C | c.48G>A p.R16= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV51435596; called by muse, mutect2, varscan2
- RAD50 | c.144T>C p.C48= | Silent (SNP) | VAF 41/179 reads (23%) | catalogued as COSV54750943; called by muse, mutect2, varscan2
- ZNF829 | c.978T>C p.C326= | Silent (SNP) | VAF 52/187 reads (28%) | catalogued as COSV66986233; called by muse, mutect2, varscan2
- AFDN | c.4812+73T>C | Intron (SNP) | VAF 33/137 reads (24%) | called by muse, mutect2, varscan2
